CGCI case BLGSP-71-30-00662 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ea0bf025-7f39-4a5c-87c9-0b8d3ae84221

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 27 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 27.8 years (10,164 days); Year of diagnosis: 2014; Method of diagnosis: Dilation and Curettage Procedure; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,063 days (5.6 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Ovary; Sites of involvement: Bone marrow / Breast, NOS / Pancreas, NOS / Ovary, NOS / Uterus / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Retroperitoneal; Tumor largest dimension diameter: 11.8 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX-M; Days to treatment start: 14 days; Days to treatment end: 99 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-IVAC; Days to treatment start: 14 days; Days to treatment end: 99 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 14 days; Days to treatment end: 99 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 2,063 days (5.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,529.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Positive.
- BCL6 (FISH): Normal.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Positive.
- CD45 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 50%.
- MYC translocation (FISH): Abnormal, NOS.
- Test (IHC): Negative; Specialized molecular test: TdT.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 924 [Blood test normal range upper: 240].

Other clinical attributes
- Day 0: Weight: 62.3 kg; Height: 164 cm; BMI: 23.2.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00662-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: FFPE; Days to sample procurement: 0 days; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00662-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00662-01-Ki67: Tissue microarray coordinates: I5,J5.
  Slide BLGSP-71-30-00662-01-EBER: Tissue microarray coordinates: I5,J5.
  Slide BLGSP-71-30-00662-01-CD3: Tissue microarray coordinates: I5,J5.
  Slide BLGSP-71-30-00662-01-CD10: Tissue microarray coordinates: I5,J5.
  Slide BLGSP-71-30-00662-01-CD20: Tissue microarray coordinates: I5,J5.
  Slide BLGSP-71-30-00662-01-BCL6: Tissue microarray coordinates: I5,J5.
  Slide BLGSP-71-30-00662-01-BCL2: Tissue microarray coordinates: I5,J5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 6; Extranodal involvment other: spleen; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: endometrial curettings; Lymph nodes examined: No; Bone marrow sample histology: Concordant Histology.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 924; Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD45.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunophenotypic analysis tested: Tdt.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Follow-up form 1: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CODOXMR/IVACR (Magrath protocol); Pharma adjuvant cycles count: 4.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00662-01A-01E-0001-01:
- % tumour: 90
